Gene-level copy-number profile of tumor specimen ALCH-B2SB-TTP1-A from ALCHEMIST case ALCH-B2SB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.1 years (28,170 days).
Specimen ALCH-B2SB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b540a47c-0b7d-4774-9d10-d1bf21db03ce.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2SB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/269a7a3e-a4b5-498b-9352-3b3afab2e967

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 2,904; copy number 2: 14,715; copy number 3: 16,884; copy number 4: 16,740; copy number 5: 2,208; copy number 6: 3,725; copy number 7: 533; copy number 8: 106; copy number 9: 162; copy number 10: 259; copy number 11: 56; copy number 13: 74.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:90,174,062–90,175,865, 1 gene (within-gene range 0–3): CICP25.
- chr18:47,285,725–49,048,474, 30 genes (within-gene range 0–1): MIR4527HG, MIR4527, AC102797.2, AC102797.1, TPMTP1, AC026898.1, SMAD2, MTCO2P2, AC120349.3, AC120349.1, AC120349.2, ZBTB7C, AC105101.1, AC105101.2, RNU6-708P, C18orf12, RNA5SP456, AC024288.1, POLR3GP2, CTIF, AC048380.2, AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1, AC016866.3, AC016866.1.
- chr18:49,049,687–49,049,768, 1 gene (within-gene range 0–1): MIR4744.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 551 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–15,939,795, 268 genes, copy number 9–13 (within-gene range 8–13) (broad region; genes not listed).
- chr5:26,880,597–28,809,291, 10 genes, copy number 10: CDH9, RNU6-738P, PURPL, AC113355.1, AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2.
- chr5:29,304,305–29,600,868, 3 genes, copy number 9: LINC02064, AC027345.1, UBL5P1.
- chr5:36,485,343–37,966,964, 29 genes, copy number 10: RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1.
- chr5:38,937,920–39,424,868, 5 genes, copy number 10 (within-gene range 7–10): RICTOR, AIG1P1, FYB1, GOLGA5P1, C9.
- chr5:179,678,628–179,731,641, 1 gene, copy number 9 (within-gene range 2–9): CANX.
- chr5:179,732,822–180,209,211, 19 genes, copy number 9: MAML1, LTC4S, MGAT4B, MIR1229, SQSTM1, MRNIP, RN7SKP150, Y_RNA, AC008393.1, TBC1D9B, RNF130, RPS15AP18, AC010285.2, AC010285.1, AC010285.3, MIR340, AC122713.2, AC122713.1, RASGEF1C.
- chr8:115,408,496–116,849,463, 8 genes, copy number 9 (within-gene range 6–9): TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23.
- chr8:117,265,272–121,119,754, 43 genes, copy number 9: AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1, MRPL13, MTBP, SNTB1, NCAPGP1, AC104958.1, AC104958.2, AC068413.1, AC011626.1.
- chr8:123,768,439–134,979,279, 165 genes, copy number 9–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,401. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
